Somatic mutation profile of tumor specimen TARGET-40-0A4HXS-01A (aliquot TARGET-40-0A4HXS-01A-01D) from TARGET case TARGET-40-0A4HXS, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 23.2 years (8,470 days).
Specimen TARGET-40-0A4HXS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2c7dfeb1-0616-418d-96b7-d2ec8cd3f9dc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-0A4HXS-10A (Blood Derived Normal), aliquot TARGET-40-0A4HXS-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0000f086-7e12-4778-bdca-959761c1d39e

The open-access MAF lists 27 somatic variants for this specimen: 15 protein-altering or splice-affecting, 4 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Intron 5, Silent 4, Nonsense Mutation 1, Splice Region 1, RNA 1, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DCLK1 | c.1205C>T p.A402V | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55201714; called by muse, mutect2, varscan2
- MYO7B | c.5636-6G>A | Splice Region (SNP) | VAF 20/101 reads (20%) | catalogued as rs750988745; called by muse, mutect2, varscan2
- TTN | c.26795C>T p.T8932M (on ENST00000591111; = p.T8005M on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/184 reads (12%) | PolyPhen benign (0.003); catalogued as rs745792278, COSV60026005, COSV60085709; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FER1L6 | c.1978G>C p.D660H | Missense Mutation (SNP) | VAF 10/143 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- FNDC3B | c.47C>T p.P16L | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- FUT5 | c.568G>C p.G190R | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); called by muse, mutect2
- HDAC1 | c.711T>A p.Y237* | Nonsense Mutation (SNP) | VAF 10/118 reads (8%) | called by muse, mutect2
- IKZF3 | c.1003G>T p.V335F | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- ITGA8 | c.1041A>C p.E347D | Missense Mutation (SNP) | VAF 5/98 reads (5%) | SIFT tolerated (0.93); PolyPhen benign (0.036); called by muse, mutect2
- LRRN3 | c.1732T>G p.Y578D | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- MAP3K13 | c.2864T>C p.V955A | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- PCDH19 | c.456C>A p.S152R | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- PRSS16 | c.290T>C p.L97P | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PTPRT | c.761T>C p.V254A | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SYCP1 | c.1366A>T p.I456F | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- FILIP1L | c.2229C>T p.H743= (on ENST00000354552 / NM_182909.3; = p.H503= on NM_014890.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 25/177 reads (14%) | called by muse, mutect2, varscan2
- PSG5 | c.699G>T p.L233= | Silent (SNP) | VAF 23/180 reads (13%) | called by muse, mutect2, varscan2
- URB1 | c.858G>A p.V286= | Silent (SNP) | VAF 63/525 reads (12%) | called by muse, mutect2, varscan2
- ZNF711 | c.501A>G p.S167= | Silent (SNP) | VAF 22/59 reads (37%) | called by muse, mutect2, varscan2
- BAIAP2 | c.279+106G>A | Intron (SNP) | VAF 5/56 reads (9%) | called by muse, mutect2
- HRCT1 | c.*95C>T | 3'UTR (SNP) | VAF 3/21 reads (14%) | called by muse, mutect2
- MPRIP | c.123+14726C>T | Intron (SNP) | VAF 175/600 reads (29%) | catalogued as rs1270763513; called by muse, mutect2, varscan2
- MROH2B | c.1684+117G>T | Intron (SNP) | VAF 22/64 reads (34%) | called by muse, mutect2
- OAZ1 | c.291+33C>G | Intron (SNP) | VAF 4/28 reads (14%) | called by muse, mutect2
- PTHLH | c.-23+235C>T | Intron (SNP) | VAF 19/182 reads (10%) | catalogued as rs1184315528; called by muse, mutect2, varscan2
- RAD51AP1 | chr12:4538827 G>A | 5'Flank (SNP) | VAF 6/22 reads (27%) | catalogued as rs1337430680; called by muse, mutect2
- TUBBP1 | n.995C>T | RNA (SNP) | VAF 16/101 reads (16%) | catalogued as rs370978820; called by muse, mutect2, varscan2
